FM case AD159 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/28307b71-e1a7-4edc-81db-173deb086b7e

Female, 43.9 years: Melanoma, NOS (ICD-O-3 8720/3). Sample type: Tumor.
